Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6405, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6405-01A (Primary Tumor).

[page 1 of 2]
TCGA-DU-6405

SURGERY DATE:

RECEIVE DATE:

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, SITE NOT SPECIFIED, BIOPSY: INFILTRATING GLIOMA.
B,C. BRAIN, SITE NOT SPECIFIED, BIOPSIES: ASTROCYTOMA WITH
ATYPICAL FEATURES.
D. BRAIN, SITE NOT SPECIFIED, EXCISION: ~~ANAPLASTIC ASTROCYTOMA~~
WHO ~~GRADE III/IV~~
MIB-1 PROLIFERATION INDEX: 23%.

SEE MICROSCOPIC DESCRIPTION AND COMMENT.

Operation/Specimen: Craniotomy, brain.

Clinical History and Pre-Op Dx: [REDACTED] with large,
diffusely infiltrating mass.

GROSS PATHOLOGY:

SPECIMEN A: Received fresh, 1 fragment, 0.4 cm across, semi-firm,
tannish/white in toto #1.

INTRAOPERATIVE CONSULTATION: Brain, site not specified: Atypical
glial proliferation.

SPECIMEN B: Received fresh, 1 fragment, 0.8 cm across, semi-firm,
tannish/brown in toto #2.

INTRAOPERATIVE CONSULTATION: Brain, smears: Astrocytoma, C/W high
histological grade.

SPECIMEN C: Received fresh, 0.7 cm across, semi-firm tannish-brown.
In toto #3.

INTRAOPERATIVE CONSULTATION: Brain, frozen section: Astrocytoma, C/W
high histological grade.

SPECIMEN D: Left frontal tumor.

FIXATIVE: Formalin.

GENERAL: Multiple small and large soft, fleshy, tan-white tissue
fragments size ranging from 0.5-2.4 cm. Cut surface is
non-homogeneous with areas of hemorrhage.

SECTIONS: X1-X5.
[REDACTED] [REDACTED]

[page 2 of 2]
MICROSCOPIC: A. Portion of cerebral cortex and adjacent white matter with slightly increased cellularity. There is an occasional atypical nucleus. There are areas of rarefaction with prominent reactive astrocytes.

B,C. Portions of brain tissue extensively infiltrated by a neoplastic proliferation of glial cells with an astrocyte phenotype. The tumor is moderately cellular, with moderate nuclear atypia. Mitotic figures are not identified. Some microvessels are prominent, however, no clear microvascular cellular proliferation is present.

D. Large portions of cerebral cortex and white matter partially or totally effaced by a glial neoplastic proliferation with features similar to those ones described for parts B and C. In here, however, there are focal areas with greater cellularity ("proliferation centers"), in which mitotic activity is readily identified. Focally, neo-formed vessels are present, but are devoid of bone fide microvascular cellular proliferation. There are no areas of necrosis.

SPECIAL STAINS: immunoperoxidase methods for GFAP and MIB-1 were performed on sections from block X5. The GFAP demonstrates the heavy fibrillary component of the neoplasm, with the MIB-1 a proliferation index of 23% is determined in a proliferation center.

COMMENT: In this brain there is an astrocytoma that infiltrates and effaces the brain. The tumor has prominent gliogenesis. The neoplastic cells have moderate nuclear atypia, and mitotic activity is confined to some more cellular areas. The proliferation index in these areas is 23%. Although neo-vessels are focally prominent, there is no definitive microvascular cellular proliferation.

These morphological features are those of an astrocytoma with focal anaplastic transformation.

Source: NCI Genomic Data Commons file 8c8fee9c-d988-48df-b436-40ded03d19ba (TCGA-DU-6405.5A26CE1C-D97C-4123-A573-A1F4EF1A6FEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).